Gene-level copy-number profile of tumor specimen HCM-CSHL-0084-C25-01A from HCMI case HCM-CSHL-0084-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.2 years (26,727 days).
Specimen HCM-CSHL-0084-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38dc493f-a947-4010-b750-4fadfbf3da8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0084-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/010870eb-3098-4e80-90ab-6fc8ad6dc2a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 18,850; copy number 2: 27,346; copy number 3: 9,920; copy number 4: 1,946; copy number 5: 40; copy number 6: 75; copy number 7: 67; copy number 8: 93; copy number 11: 26; copy number 14: 12; copy number 34: 13; copy number 39: 9.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,690,719, 3 genes (within-gene range 0–1): AC104164.2, MIR548BB, PPIAP70.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 335 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 6: CFHR3.
- chr8:125,998,994–128,187,101, 34 genes, copy number 14–39 (within-gene range 2–39): AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr9:35,406,755–38,147,561, 99 genes, copy number 6–8 (broad region; genes not listed).
- chr17:38,419,280–41,734,644, 201 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,975. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
